Somatic mutation profile of tumor specimen C3L-05896-54 (aliquot CPT0344840002) from CPTAC case C3L-05896, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 44.6 years (16,305 days).
Specimen C3L-05896-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9387fbf3-f9f9-4517-85ea-63308d18a510.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05896-50 (Buccal Cell Normal), aliquot CPT0344810003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45c76bbd-f43a-4ee6-b772-46b5a6558cc1

The open-access MAF lists 20 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Del 2, Splice Region 2, Frame Shift Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2516A>G p.D839G | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs991132188, COSV54045448; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 17/76 reads (22%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 67/420 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- BTK | c.1349+5G>T | Splice Region (SNP) | VAF 8/246 reads (3%) | catalogued as CS086389, CS951366, CS983696; called by muse, mutect2
- DCPS | c.377-1G>C p.X126_splice | Splice Site (SNP) | VAF 37/76 reads (49%) | catalogued as COSV55010746; called by muse, mutect2
- GRM5 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs747882335, COSV59631715; called by muse, mutect2, varscan2
- MAPT | c.898G>A p.D300N (on ENST00000262410 / NM_001377265.1; = p.D225N on NM_016835.4) | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs779635238; called by muse, mutect2, varscan2
- OR1S1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374879241, COSV58707276; called by muse, mutect2
- TSSK1B | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs373430280; called by muse, mutect2, varscan2
- ZNF416 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1469936114; called by muse, mutect2, varscan2
- CIZ1 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 111/212 reads (52%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CTXN2 | c.85del p.T29Lfs*25 | Frame Shift Del (DEL) | VAF 106/276 reads (38%) | called by mutect2, pindel, varscan2
- FANCB | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- GALK2 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1614 | c.2578T>A p.S860T | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- NVL | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBPL7 | c.798T>C p.V266= | Splice Region (SNP) | VAF 75/198 reads (38%) | called by muse, mutect2, varscan2
- STAG2 | c.1544_1547del p.D515Gfs*6 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- SULT1E1 | c.415T>C p.Y139H | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT6A | c.*20G>A | 3'UTR (SNP) | VAF 78/177 reads (44%) | catalogued as rs1053748; called by muse, mutect2, varscan2
